Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A3EH, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A3EH-01A (Primary Tumor).

Sex: Female
D.O.B.: [REDACTED]

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Breast, right, axillary contents; modified radical mastectomy and axillary node dissection:

Tumor Characteristics:

1. Histologic type: Pleomorphic lobular carcinoma, confirmed by negative e-cadherin stain.
2. Size: 10.0 x 10.0 x 7.2 cm.
3. Tumor focality: Unifocal.
4. Elston modification of Bloom-Richardson grade:
- a. Architectural score: 3/3.
- b. Nuclear score: 2/3.
- c. Mitotic score: 1/3.
- d. Total score: 6/9 = Grade: II.
5. In situ component: Not identified.
6. Lymphovascular space invasion: Present.
7. Skin involvement: Not identified.
8. Microcalcifications: Present and associated with invasive carcinoma.

Surgical Margin Status:

1. Deep surgical margin free of tumor by 2.5 cm as measured grossly.

Lymph Node Status:

1. Total number of lymph nodes received: 12.
2. Total number of lymph nodes containing metastatic carcinoma:
3. Size of largest metastasis: 2.5 cm.
4. Extracapsular extension of tumor: Present.
- Other:
1. pTNM stage: pT3 N2.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right MET
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

Right breast and axillary contents
at

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received [REDACTED] right breast and axillary contents the specimen consists of a portion of fibroadipose breast tissue and overlying skin that measures 18.0 by 8.0 cm and weighs 1,529 gm. The skin surface measures 23.0 x 13.8 cm is light tan wrinkled there is a scar within the outer quadrant measuring 3.0 cm that is 9.2 cm in the nipple there is slight ecchymosis noted within the upper outer quadrant. No other lesions are identified. The nipple is eccentrically placed appears grossly unremarkable. Sectioning reveals a firm gray-tan lobular mass that measures 10.0 x 10.0 x 7.2 cm that is centrally located it is within 2.5 cm of the deep margin of resection the surrounding breast tissue reveals yellow-tan fatty fibroadipose tissue with areas of gray fibrous tissue. Attached to the specimen is a portion of axillary contents measuring 10.0 x 6.0 x 3.0 cm there are twelve possible lymph nodes that measure from 0.3 to 2.7 cm. Received with the specimen is a separate piece of skin and underlying subcutaneous tissue 14.0 x 4.0 x 1.5 cm sectioning cut surface is yellow-tan fatty fibroadipose tissue lesions not identified grossly. Received with specimen are three cassettes labeled [REDACTED] with a yellow one additionally labeled -18 green one additionally labeled -17 and the blue one additionally labeled -18. Representative sections are submitted in cassettes labeled [REDACTED] as follows: Nipple - block 1; Deep margin overlying mass - block 2; Sections from the mass - blocks 3-8; Random sections from the upper inner quadrant - block 9; Lower inner quadrant - block 10; Lower outer quadrant - block 11; Upper outer quadrant - block 12; Six probable nodes - block 13; Two probable nodes each bisected - block 14; One probable node bisected - block 15; One probable node trisected - block 16-18; One probable node bisected - block 19; One probable lymph node sectioned - blocks 20-23; Sections from separately

ICD-0-3

carcinoma, pleomorphic 8022/3
(invasive lobular)

Site: breast, C50.9 lw 10/31/11

Source: NCI Genomic Data Commons file 15b968cb-3401-4f23-b75d-101a1815ad7e (TCGA-AC-A3EH.3094774B-B764-4D60-BFF3-48FEF39F4BEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).